Somatic mutation profile of tumor specimen C3L-06953-54 (aliquot CPT0395220002) from CPTAC case C3L-06953, project CPTAC-3 (Hematopoietic and reticuloendothelial systems — Myeloid Leukemias). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 71.5 years (26,105 days).
Specimen C3L-06953-54: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 05b88010-7484-4602-b46a-580c16632060.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-06953-51 (Buccal Cell Normal), aliquot CPT0395300002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1925cc58-967c-4112-b4c2-130d98dc80c1

The open-access MAF lists 11 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Splice Region 1, Intron 1, 5'UTR 1, 3'Flank 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DNAH14 | c.467C>G p.P156R | Missense Mutation (SNP) | VAF 112/234 reads (48%) | catalogued as rs891751218; called by muse, mutect2, varscan2
- ELAVL3 | c.320C>A p.T107K | Missense Mutation (SNP) | VAF 117/218 reads (54%) | SIFT deleterious (0.02); PolyPhen benign (0.056); catalogued as COSV63647681; called by muse, mutect2, varscan2
- CASP3 | c.452T>G p.L151R | Missense Mutation (SNP) | VAF 54/116 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- DPP4 | c.417A>G p.K139= | Splice Region (SNP) | VAF 60/134 reads (45%) | called by muse, mutect2, varscan2
- FREM1 | c.6326A>C p.K2109T | Missense Mutation (SNP) | VAF 64/130 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); called by muse, mutect2, varscan2
- PI16 | c.628C>A p.P210T | Missense Mutation (SNP) | VAF 35/79 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- SLC44A3 | c.1873A>G p.S625G (on ENST00000271227 / NM_001114106.3; = p.S577G on NM_152369.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 58/149 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- MGAT3 | c.1098G>A p.T366= | Silent (SNP) | VAF 85/204 reads (42%) | catalogued as rs1355896903; called by muse, mutect2, varscan2
- FBXL7 | c.-58A>C | 5'UTR (SNP) | VAF 26/376 reads (7%) | called by muse, mutect2
- PBK | chr8:27808232 A>C | 3'Flank (SNP) | VAF 28/66 reads (42%) | called by muse, mutect2, varscan2
- PHC3 | c.378+11T>A | Intron (SNP) | VAF 74/182 reads (41%) | called by muse, varscan2
